Somatic mutation profile of tumor specimen TCGA-AO-A0J4-01A (aliquot TCGA-AO-A0J4-01A-11W-A050-09) from TCGA case TCGA-AO-A0J4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 41.2 years (15,052 days).
Specimen TCGA-AO-A0J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c0565cb-b76a-4945-96c7-da53c6fef61c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0J4-10A (Blood Derived Normal), aliquot TCGA-AO-A0J4-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e6702e3-3950-4a23-a9c4-afefa989efed

The open-access MAF lists 116 somatic variants for this specimen: 88 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 26, Nonsense Mutation 6, Frame Shift Del 2, Intron 1, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 88/210 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.2019A>T p.K673N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62418862; called by muse, mutect2, varscan2
- ARHGAP30 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV63519246; called by muse, mutect2, varscan2
- ARHGEF10 | c.265G>T p.G89* (on ENST00000398564; = p.G65* on NM_014629.4) | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100035281; called by muse, mutect2
- ATMIN | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55147573; called by muse, mutect2, varscan2
- B3GALT5 | c.221T>G p.M74R | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as COSV100563456; called by muse, mutect2
- BMP5 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 19/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100896235; called by muse, mutect2
- C1orf210 | c.58G>C p.V20L | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV70682561; called by muse, mutect2, varscan2
- C9orf72 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | catalogued as COSV101186543, COSV101186548; called by muse, mutect2
- CACNA1B | c.3364C>T p.R1122W | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201227447, COSV53116181; called by muse, mutect2, varscan2
- CCSER1 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 52/101 reads (51%) | catalogued as COSV61467139; called by muse, mutect2, varscan2
- CD244 | c.1099G>A p.D367N (on ENST00000368033 / NM_001166663.2; = p.D362N on NM_016382.4) | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.374); catalogued as COSV54433107, COSV99627263; called by muse, mutect2
- CEP152 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as rs368723147, COSV57864718; called by muse, mutect2, varscan2
- CKMT2 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54174986; called by muse, mutect2, varscan2
- CLTCL1 | c.3826A>C p.I1276L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.075); catalogued as COSV54238807; called by muse, mutect2, varscan2
- CNTNAP2 | c.3850C>T p.R1284W | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763809167, COSV62169295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2A13 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV57840030; called by muse, mutect2, varscan2
- DHX57 | c.3461G>C p.R1154T | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1305475168, COSV54891044; called by muse, mutect2, varscan2
- DNAH3 | c.10887C>G p.I3629M | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs760574855, COSV54550282; called by muse, mutect2, varscan2
- DSCAM | c.5017G>C p.D1673H | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1431666296, COSV101261206; called by muse, mutect2
- DZIP1L | c.2257G>C p.G753R | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV59523386; called by muse, mutect2, varscan2
- EXD2 | c.1443C>G p.F481L (on ENST00000312994 / NM_001193362.1; = p.F356L on NM_018199.3) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV57282116; called by muse, mutect2, varscan2
- FAM219B | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV62947253; called by muse, mutect2, varscan2
- FAT3 | c.8476G>T p.G2826W | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53171927; called by muse, mutect2, varscan2
- FBN1 | c.6773G>C p.C2258S | Missense Mutation (SNP) | VAF 15/467 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CD152330, CM993161, COSV100356076, COSV57328175; called by muse, mutect2
- FCN1 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100878954; called by muse, mutect2
- FGF6 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746672335, COSV57403329; called by muse, mutect2, varscan2
- GBF1 | c.5209C>G p.L1737V (on ENST00000369983 / NM_001377137.1; = p.L1736V on NM_004193.3) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV64148896; called by muse, mutect2, varscan2
- GRAMD4 | c.965A>T p.K322M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63032563; called by muse, mutect2, varscan2
- GYS2 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767722149, COSV53928734; called by muse, mutect2, varscan2
- HNRNPH2 | c.1329C>A p.D443E | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.092); catalogued as COSV57267427; called by muse, mutect2, varscan2
- IQSEC1 | c.1405G>C p.D469H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56228983; called by muse, mutect2, varscan2
- KIF4A | c.560C>G p.T187S | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV65544850, COSV65545776; called by muse, mutect2, varscan2
- KMT2E | c.5527C>A p.Q1843K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV57579522; called by muse, mutect2, varscan2
- KRTAP1-1 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1447846436, COSV60397816; called by muse, mutect2
- L3MBTL2 | c.1670C>T p.T557M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781625142, COSV53435709; called by muse, mutect2, varscan2
- LAYN | c.220G>A p.D74N (on ENST00000375615 / NM_001258390.1; = p.D66N on NM_178834.5) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV65105513; called by muse, mutect2, varscan2
- LCN10 | c.524del p.L175Pfs*? (on ENST00000474369 / NM_001368089.1; = p.L188Pfs*50 on NM_001001712.3) | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | catalogued as COSV57911571; called by mutect2, pindel, varscan2
- LRP2 | c.7220A>G p.N2407S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.077); catalogued as COSV55573483; called by muse, mutect2, varscan2
- LRRK2 | c.5117C>G p.S1706* | Nonsense Mutation (SNP) | VAF 11/162 reads (7%) | catalogued as COSV54169965; called by muse, mutect2
- MFN1 | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54942418; called by muse, mutect2, varscan2
- MSH6 | c.2076A>C p.K692N | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV52287478; called by muse, mutect2, varscan2
- MTMR4 | c.2899C>G p.H967D | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.072); catalogued as COSV60203669; called by muse, mutect2
- NCAPD2 | c.3245T>C p.L1082P | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59702442; called by muse, mutect2, varscan2
- NCKAP5 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1278094074, COSV100493829, COSV58481105; called by muse, mutect2
- NRROS | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60747758; called by muse, mutect2, varscan2
- OLFML3 | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.291); catalogued as COSV57436966; called by muse, mutect2, varscan2
- OR2T3 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 78/776 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs762738891, COSV62083659; called by muse, mutect2, varscan2
- OR6X1 | c.909G>C p.M303I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60010446; called by muse, mutect2, varscan2
- P2RY2 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60777726; called by muse, mutect2, varscan2
- PCBP2 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100827728; called by muse, mutect2
- PCNX1 | c.4187C>A p.A1396D | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53101619; called by muse, mutect2, varscan2
- PM20D2 | c.1125G>C p.L375F | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs1223934019, COSV99248484; called by muse, mutect2
- PODN | c.153G>C p.Q51H (on ENST00000395871; = p.Q3H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as COSV57017229; called by muse, mutect2, varscan2
- PPP1R12A | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54113876; called by muse, mutect2, varscan2
- PPP4R2 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV55597928; called by muse, mutect2, varscan2
- PRAM1 | c.491C>G p.A164G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs1014602389, COSV99725791; called by muse, mutect2
- PRF1 | c.1435A>T p.R479W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64615831; called by muse, mutect2, varscan2
- PRPF4B | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV61785777; called by muse, mutect2, varscan2
- PRR11 | c.193A>T p.N65Y | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV51879220; called by muse, mutect2, varscan2
- PRRC2B | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622093; called by muse, mutect2
- RALGAPB | c.2977C>G p.L993V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs1242298174, COSV99485597; called by muse, mutect2
- RGS22 | c.1130C>G p.S377* | Nonsense Mutation (SNP) | VAF 93/419 reads (22%) | catalogued as COSV62667422; called by muse, mutect2, varscan2
- SLC11A1 | c.1011C>A p.N337K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as rs756884699, COSV51919508; called by muse, mutect2, varscan2
- SLC28A1 | c.1903C>G p.L635V | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs17222421; called by muse, mutect2
- SLIT2 | c.1433del p.C478Ffs*19 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | catalogued as COSV56591404, COSV56594651; called by mutect2, pindel, varscan2
- SMTN | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60779778; called by muse, mutect2, varscan2
- SP100 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 12/266 reads (5%) | catalogued as COSV99893910; called by muse, mutect2
- SPECC1L | c.3035C>T p.S1012L | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58657647; called by muse, mutect2
- STXBP5 | c.2422G>A p.D808N (on ENST00000321680 / NM_001127715.2; = p.D772N on NM_139244.4) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV51658037; called by muse, mutect2, varscan2
- SYNE4 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV61011024; called by muse, mutect2, varscan2
- TBC1D2B | c.2777A>G p.E926G (on ENST00000300584 / NM_144572.1; = p.R909G on NM_015079.6) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56046139; called by muse, mutect2, varscan2
- TBX15 | c.1765G>A p.A589T (on ENST00000369429 / NM_001330677.2; = p.A483T on NM_152380.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.075); catalogued as COSV99254578; called by muse, mutect2
- TBX15 | c.1160G>A p.R387Q (on ENST00000369429 / NM_001330677.2; = p.R281Q on NM_152380.3) | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.953); catalogued as rs1339052659, COSV52867582; called by muse, mutect2, varscan2
- TMCO4 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV99617304; called by muse, mutect2, varscan2
- TP53I3 | c.427T>G p.Y143D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99272948; called by muse, mutect2
- TTC24 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs750349500, COSV63998463; called by muse, mutect2, varscan2
- TWNK | c.2010G>C p.Q670H | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.085); catalogued as rs778236767, COSV61328820; called by muse, mutect2
- TYW1 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs748628175, COSV62753219, COSV62753481, COSV62756074; called by muse, mutect2, varscan2
- USH2A | c.12379C>A p.L4127I | Missense Mutation (SNP) | VAF 55/421 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV56433379; called by muse, mutect2, varscan2
- USP38 | c.773C>G p.T258R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV100189416; called by muse, mutect2
- VWCE | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV100076073; called by muse, mutect2
- VWF | c.5160A>T p.K1720N | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.233); catalogued as COSV54621487; called by muse, mutect2, varscan2
- XIRP2 | c.8455G>A p.E2819K (on ENST00000628543; = p.E2994K on NM_152381.6) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1342838227, COSV54733013; called by muse, mutect2, varscan2
- ZMYM4 | c.1813T>G p.Y605D | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV58917046; called by muse, mutect2, varscan2
- ACACA | c.3859G>C p.D1287H | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- AGTR1 | c.149_150insCATTTACTTTTATATGAAGCTGAAGACAGCTT p.V52Yfs*10 | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | called by mutect2, pindel*
- PHACTR2 | c.1329_1334del p.S445_D446del | In Frame Del (DEL) | VAF 38/180 reads (21%) | called by pindel, varscan2
- ABCF3 | c.1566T>C p.C522= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs370941899; called by muse, mutect2, varscan2
- ADCY8 | c.618C>G p.A206= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as COSV53926518; called by muse, mutect2, varscan2
- ADGRL3 | c.2103C>T p.A701= (on ENST00000506720 / NM_001322402.2; = p.A633= on NM_015236.6) | Silent (SNP) | VAF 29/240 reads (12%) | catalogued as rs1239702267, COSV72231366, COSV72231908; called by muse, mutect2, varscan2
- ASAP1 | c.1311G>C p.L437= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV63054299; called by muse, mutect2, varscan2
- DNAH2 | c.7011C>A p.I2337= | Silent (SNP) | VAF 13/239 reads (5%) | catalogued as COSV101209530; called by muse, mutect2
- EPS15L1 | c.1080G>A p.P360= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs776274888, COSV50175029; called by muse, mutect2, varscan2
- GART | c.1095G>A p.L365= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV63114664; called by muse, mutect2, varscan2
- GMPR | c.600T>C p.S200= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV52475387; called by muse, mutect2, varscan2
- GSTM5 | c.168C>T p.D56= | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as rs746469769, COSV56660219; called by muse, mutect2
- H2BU1 | c.301C>T p.L101= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV64210220; called by muse, mutect2
- HELZ | c.1800C>G p.L600= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as COSV62380895; called by muse, mutect2
- LIFR | c.1719A>G p.V573= | Silent (SNP) | VAF 85/188 reads (45%) | catalogued as rs183990367, COSV54699447; called by muse, mutect2, varscan2
- MICAL2 | c.288C>G p.P96= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV56326212; called by muse, mutect2, varscan2
- NOL4 | c.111C>G p.V37= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV52361461; called by muse, mutect2, varscan2
- OR2F1 | c.828C>G p.V276= | Silent (SNP) | VAF 22/282 reads (8%) | catalogued as COSV67332058; called by muse, mutect2
- PLEKHA4 | c.1422C>G p.P474= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV54366101; called by muse, mutect2, varscan2
- PLEKHN1 | c.1456A>C p.R486= (on ENST00000379409; = p.R434= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV58023771; called by muse, mutect2
- PPEF1 | c.66C>T p.I22= | Silent (SNP) | VAF 70/216 reads (32%) | catalogued as COSV62996711; called by muse, mutect2, varscan2
- PSIP1 | c.399G>C p.V133= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV66255648; called by muse, mutect2, varscan2
- PTPRZ1 | c.3171T>A p.P1057= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV66445280; called by muse, mutect2
- RGR | c.558C>T p.F186= | Silent (SNP) | VAF 45/130 reads (35%) | catalogued as rs1448411233, COSV63895170; called by muse, mutect2, varscan2
- RIMS2 | c.714T>C p.S238= (on ENST00000666250 / NM_001348490.2; = p.S46= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 14/183 reads (8%) | catalogued as rs749766002, COSV99184721; called by muse, mutect2
- SAMD9L | c.2433C>G p.V811= | Silent (SNP) | VAF 24/274 reads (9%) | catalogued as rs745666788, COSV100561046; called by muse, mutect2
- STX6 | c.528C>T p.V176= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV51114014; called by muse, mutect2, varscan2
- TNFAIP3 | c.1977G>T p.G659= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV52802131; called by muse, mutect2, varscan2
- UGT1A3 | c.414C>T p.I138= | Silent (SNP) | VAF 105/306 reads (34%) | catalogued as COSV59398235; called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509061 A>G | 5'Flank (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.10303+2390C>G | Intron (SNP) | VAF 18/172 reads (10%) | catalogued as COSV60337606; called by muse, mutect2, varscan2
